Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XA, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XA-01A (Primary Tumor).

[page 1 of 2]
Proced
Receiv
Report

Final Diagnosis:

A-B. Brain, left temporal occipital lesion #1-#2, excision: Low grade oligoastrocytoma (WHO grade II).

Immunohistochemistry is performed on paraffin-embedded sections against the following antigens: IDH-1, GFAP, p53, and Ki-67. Tumor cells are positive for IDH-1 (R132H). Occasional tumor cells stain for GFAP. However, many of the tumor cells lack GFAP reactivity. P53 shows low to moderate staining, whereas Ki-67 shows focally moderate staining. These immunohistochemical features support the above diagnosis.

Fluorescence in situ hybridization (FISH) for 1p/19q deletion is pending.

Preliminary Frozen Section Consultation:

A. Brain, left temporal occipital lesion #1, smears: Low-grade glioma, probably oligodendroglioma.

continued next page Page 1 of 2

100-6-3
Oligo astrocytoma 9382/3
Site: brain, temporal lobe C71.2
hw
10/23/12

[page 2 of 2]
Seen in consultation with:

Intraoperative cytologic smear(s) interpretation performed by:

Gross Description:

A. Received fresh labeled "left temporal occipital lesion - brain" is a 2.5 x 2.2 x 0.8 cm portion of brain. Smears prepared. Representative sections are submitted. Grossed by

B. Received fresh labeled "left temporal occipital lesion - brain #2" is a 2.0 x 1.2 x 1.0 cm portion of brain. All submitted for permanent sections only. Grossed by

Block Summary:

Part A: Left temporal occipital lesion-brain

- 1 Lt temporal occipital 1
- 2 Lt temporal occipital 2
- 3 Lt temporal occipital 3
- 4 Lt temporal occipital 4

Part B: Left temporal occipital lesion-brain #2

- 1 Lt temporal occipital #2-1
- 2 Lt temporal occipital #2-2
- 3 Lt temporal occipital #2-3
- 4 Lt temporal occipital #2-4
- 5 Lt temporal occipital #2-5
- 6 Lt temporal occipital #2-6

.D., Ph.D.

END OF REPORT

Page 2 of 2

HPV/A Discrepancy		☒

Source: NCI Genomic Data Commons file 1e02d323-514f-44ec-9661-db2a385461d4 (TCGA-DB-A4XA.8DCE6400-9767-46DD-A965-5B02FEB3F156.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).